MMRF case MMRF_2614 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5f1be704-5a13-44a6-8ba0-b277620c7d87

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.3 years (21,292 days); ISS stage: I; Days to last known disease status: 563 days (1.5 years); Days to last follow up: 563 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 181 days; Days to treatment end: 181 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 184 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 2.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.982 mg/dL; Immunoglobulin G 32.3 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.15 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 8.9 g/dL; Glucose 4.9 mmol/L; C-Reactive Protein 0.81 mg/dL.
- Day 69 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 4.47 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 5.39 mmol/L.
- Day 160 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.702 mg/dL; Immunoglobulin G 6.16 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 6.6 mmol/L.
- Day 290 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 8.81 g/L; Immunoglobulin A 2.73 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 510 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 9.22 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 4.02 mmol/L.
- Day 563: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day 1: Weight: 76 kg; Height: 173 cm.

Biospecimens (2 samples)
- Sample MMRF_2614_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2614_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
